FM case AD6661 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/747a2302-27f3-45fe-94d0-0b362f3c5c59

Male, 66.7 years: diagnosis not reported by GDC; metastasis biopsied or resected from the testis. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
